Somatic mutation profile of tumor specimen 21c6f56a-8881-421b-81fa-c354cb (aliquot 21c6f56a-8881-421b-81fa-c354cb_D6_1) from CPTAC case 11CO022, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA.
Specimen 21c6f56a-8881-421b-81fa-c354cb: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db3e2c45-7b39-4d64-9015-1f0779ff5650.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 71dedc2c-428f-4229-aadb-c149cd (Blood Derived Normal), aliquot 71dedc2c-428f-4229-aadb-c149cd_D1_2; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22d0ee19-ec9c-46ac-91b2-397580b6803c

The open-access MAF lists 190 somatic variants for this specimen: 122 protein-altering or splice-affecting, 41 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 41, Intron 16, Nonsense Mutation 10, RNA 7, In Frame Del 4, Splice Site 3, Splice Region 2, 5'UTR 1, Nonstop Mutation 1, 3'UTR 1, IGR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 84/213 reads (39%) | catalogued as rs786201856, CM920030, COSV57325157; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNGA3 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 76/263 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs137852608, CM980378, COSV55621988; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RELN | c.9526G>A p.E3176K | Missense Mutation (SNP) | VAF 162/362 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as rs794727999, CM155185; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCF3 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141535158; called by muse, mutect2, varscan2
- AC104389.6 | c.462G>T p.K154N | Missense Mutation (SNP) | VAF 117/414 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57963803, COSV57964707; called by muse, mutect2, varscan2
- ADAMTS20 | c.2464-7T>C | Splice Region (SNP) | VAF 52/151 reads (34%) | catalogued as rs770105162; called by muse, mutect2, varscan2
- ARHGAP31 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 124/471 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs200063238; called by muse, mutect2, varscan2
- ARHGAP31 | c.1846C>T p.R616* | Nonsense Mutation (SNP) | VAF 54/198 reads (27%) | catalogued as rs754254146; called by muse, varscan2
- CACNB3 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs901128138, COSV56396951; called by muse, mutect2, varscan2
- CDC40 | c.1528T>A p.Y510N | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1456494215; called by muse, mutect2, varscan2
- CYFIP2 | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs758726132, COSV59052942; called by muse, mutect2, varscan2
- EPHA1 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 163/359 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs74721927, COSV51971522; called by muse, mutect2, varscan2
- EXOC4 | c.1574G>C p.R525P | Missense Mutation (SNP) | VAF 122/363 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.415); catalogued as rs776629991; called by muse, mutect2, varscan2
- FAM110B | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.3); catalogued as rs760950128, COSV64066479; called by muse, mutect2, varscan2
- FBXL7 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 105/374 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV61646319; called by muse, mutect2, varscan2
- FDXR | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772347757, COSV53120117; called by muse, mutect2, varscan2
- GLIS1 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 125/384 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs370494270; called by muse, mutect2, varscan2
- GPX5 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV101297252, COSV69079322; called by muse, mutect2, varscan2
- GRIN1 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 173/592 reads (29%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.958); catalogued as rs774822539, COSV59294089; called by muse, mutect2, varscan2
- H4C12 | c.311G>C p.*104Sext*? | Nonstop Mutation (SNP) | VAF 24/57 reads (42%) | catalogued as COSV62743637, COSV62743749; called by muse, mutect2, varscan2
- HCK | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs202001086; called by muse, mutect2, varscan2
- HGD | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 76/320 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs780063156; called by muse, mutect2, varscan2
- KALRN | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53760070; called by muse, mutect2, varscan2
- KIAA1549L | c.3308G>A p.R1103Q (on ENST00000321505; = p.R1400Q on NM_012194.3) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376568090, COSV55778848; called by muse, mutect2, varscan2
- KLF14 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 285/622 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1554470843; called by muse, mutect2, varscan2
- KLK5 | c.433T>C p.Y145H | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs753259668; called by muse, mutect2, varscan2
- LILRB2 | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 71/235 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV58743887; called by muse, mutect2, varscan2
- LRRC7 | c.3477C>A p.S1159R (on ENST00000651989 / NM_001370785.2; = p.S1126R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 120/428 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV50443897, COSV99226586; called by muse, mutect2, varscan2
- MAGEC2 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 64/86 reads (74%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs151260524; called by muse, mutect2, varscan2
- MKRN2OS | c.4C>T p.H2Y | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs1192630087; called by muse, mutect2, varscan2
- MR1 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 58/217 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1368060940, COSV51580280; called by muse, mutect2, varscan2
- MUC16 | c.41321C>G p.S13774C | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as COSV101110118; called by muse, mutect2, varscan2
- MYOZ2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 69/267 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748259386, COSV61085069; called by muse, mutect2, varscan2
- NBPF20 | c.137A>C p.Q46P | Missense Mutation (SNP) | VAF 86/434 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as rs1553666777; called by muse, mutect2, varscan2
- NSD3 | c.2974A>T p.K992* | Nonsense Mutation (SNP) | VAF 99/171 reads (58%) | catalogued as rs1325929010; called by muse, mutect2, varscan2
- OBP2B | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 108/359 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as rs546901290, COSV100922867; called by muse, mutect2
- OR10AG1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.079); catalogued as rs564411786, COSV56631895, COSV56632573; called by muse, mutect2, varscan2
- OR5B12 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56904755, COSV56905585; called by muse, varscan2
- PIEZO1 | c.5777G>T p.R1926L | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs753296407; called by muse, mutect2, varscan2
- RIMBP2 | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs755352610, COSV99898498; called by muse, mutect2, varscan2
- RIMS1 | c.2659C>T p.R887* | Nonsense Mutation (SNP) | VAF 24/69 reads (35%) | catalogued as rs760443753, COSV53437502, COSV53459593; called by muse, mutect2, varscan2
- RIMS2 | c.4015G>A p.V1339I | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as rs763095202, COSV51663715; called by muse, mutect2, varscan2
- RSBN1L | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 94/404 reads (23%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.342); catalogued as rs780109937; called by muse, mutect2, varscan2
- SCN5A | c.4877G>A p.R1626H (on ENST00000333535 / NM_198056.3; = p.R1625H on NM_000335.5) | Missense Mutation (SNP) | VAF 35/320 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs199473283, CM004143, CM087239, COSV100350451; ClinVar: not provided / conflicting interpretations of pathogenicity / uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SFT2D2 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 62/200 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54799279, COSV54800954; called by muse, mutect2, varscan2
- SRSF11 | c.1320_1322del p.E441del | In Frame Del (DEL) | VAF 60/232 reads (26%) | catalogued as rs1428529989; called by pindel, varscan2
- STEAP3 | c.1462G>A p.V488I | Missense Mutation (SNP) | VAF 115/378 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as rs759879690, COSV61529700; called by muse, mutect2, varscan2
- TNIP3 | c.907C>G p.L303V | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.121); catalogued as COSV50247205; called by muse, mutect2, varscan2
- TNRC18 | c.1730A>T p.H577L | Missense Mutation (SNP) | VAF 65/263 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs945673465; called by muse, mutect2, varscan2
- TNS2 | c.1147C>T p.R383* (on ENST00000314250 / NM_170754.4; = p.R393* on NM_015319.2) | Nonsense Mutation (SNP) | VAF 33/148 reads (22%) | catalogued as rs1228588606, COSV58581818; called by muse, mutect2, varscan2
- TNS3 | c.1023A>G p.E341= | Splice Region (SNP) | VAF 50/104 reads (48%) | catalogued as rs551674177; called by muse, mutect2, varscan2
- TP53 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 78/180 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs750600586, CM123559, COSV52661339, COSV52708439, COSV53502932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPO | c.1183G>A p.G395S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.76); PolyPhen benign (0.144); catalogued as rs1270250888; called by muse, mutect2, varscan2
- TTN | c.47957G>A p.R15986H (on ENST00000591111; = p.R8562H on NM_003319.4) | Missense Mutation (SNP) | VAF 63/222 reads (28%) | PolyPhen probably damaging (0.917); catalogued as rs536494011, COSV60145901; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUT7 | c.1741G>T p.V581L | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1352142027; called by muse, mutect2, varscan2
- VSNL1 | c.419T>C p.M140T | Missense Mutation (SNP) | VAF 85/283 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.117); catalogued as rs989216161; called by muse, mutect2, varscan2
- WFS1 | c.2521G>T p.E841* | Nonsense Mutation (SNP) | VAF 39/134 reads (29%) | catalogued as rs762556590; called by muse, mutect2, varscan2
- ZNF667 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 81/288 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as rs756427747; called by muse, mutect2, varscan2
- ABCB6 | c.1297G>C p.E433Q | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC134980.2 | c.733A>T p.I245F | Missense Mutation (SNP) | VAF 84/500 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.072); called by muse, varscan2
- ADAM29 | c.485T>A p.M162K | Missense Mutation (SNP) | VAF 80/286 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ANK2 | c.6757A>C p.K2253Q | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ASPH | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 50/177 reads (28%) | called by muse, mutect2, varscan2
- ATP13A5 | c.3199C>A p.P1067T | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C2orf16 | c.340C>G p.Q114E | Missense Mutation (SNP) | VAF 86/255 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- CCDC158 | c.3050A>T p.K1017M | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCR3 | c.214T>G p.Y72D | Missense Mutation (SNP) | VAF 69/288 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CFAP74 | c.3330G>T p.E1110D | Missense Mutation (SNP) | VAF 123/195 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CRACR2A | c.1111T>C p.F371L | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRK | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.149); called by muse, mutect2
- DCDC1 | c.3776C>A p.A1259D (on ENST00000597505 / NM_001367979.1; = p.A366D on NM_020869.3) | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- DEFB110 | c.6G>T p.K2N | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, varscan2
- DGKB | c.1035+1G>C p.X345_splice | Splice Site (SNP) | VAF 94/243 reads (39%) | called by muse, mutect2, varscan2
- DNAH9 | c.8996A>C p.N2999T | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- DNAJC1 | c.119C>A p.A40D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- DNMT3B | c.905T>G p.M302R | Missense Mutation (SNP) | VAF 30/524 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.057); called by muse, mutect2
- DST | c.21565G>C p.E7189Q (on ENST00000361203 / NM_001374722.1; = p.E4886Q on NM_015548.5) | Missense Mutation (SNP) | VAF 79/276 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EHMT1 | c.119A>G p.E40G | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- ELOVL2 | c.404T>G p.L135W | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENTPD7 | c.17_37del p.F6_A12del | In Frame Del (DEL) | VAF 5/45 reads (11%) | called by mutect2, pindel
- FCHO1 | c.2642C>T p.A881V | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- FSIP2 | c.11059C>A p.L3687I | Missense Mutation (SNP) | VAF 100/253 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GLIPR1L2 | c.859A>G p.M287V | Missense Mutation (SNP) | VAF 96/266 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- GLYR1 | c.469A>T p.K157* | Nonsense Mutation (SNP) | VAF 90/253 reads (36%) | called by muse, mutect2, varscan2
- GUCY2F | c.979T>G p.F327V | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- HMGXB3 | c.1826C>A p.S609Y (on ENST00000613459; = p.S363Y on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- HNMT | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 30/361 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIAA0100 | c.4277A>C p.H1426P | Missense Mutation (SNP) | VAF 101/334 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- KIF13B | c.1208T>G p.L403R | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- KRT26 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 101/324 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- KRT72 | c.1085A>C p.K362T | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, varscan2
- LILRB1 | c.76C>T p.H26Y | Missense Mutation (SNP) | VAF 43/237 reads (18%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- LIN9 | c.445A>G p.K149E (on ENST00000366808 / NM_001270410.2; = p.K94E on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- LRRC49 | c.1010A>G p.K337R | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- MAP3K21 | c.538C>T p.H180Y | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MATK | c.686T>A p.L229* (on ENST00000310132 / NM_139355.3; = p.L230* on NM_002378.4) | Nonsense Mutation (SNP) | VAF 64/210 reads (30%) | called by muse, mutect2, varscan2
- MBD5 | c.216+1G>A p.X72_splice | Splice Site (SNP) | VAF 57/188 reads (30%) | called by muse, mutect2, varscan2
- MITF | c.1530G>C p.M510I (on ENST00000448226 / NM_006722.3; = p.M410I on NM_000248.4) | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MOK | c.779C>G p.S260C | Missense Mutation (SNP) | VAF 74/118 reads (63%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MUC12 | c.11086A>T p.S3696C (on ENST00000379442; = p.S3553C on NM_001164462.1) | Missense Mutation (SNP) | VAF 92/749 reads (12%) | SIFT deleterious (0); called by mutect2, varscan2
- NALCN | c.4646A>T p.Q1549L | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NDN | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.61); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- NF1 | c.7056T>A p.N2352K (on ENST00000358273 / NM_001042492.3; = p.N2331K on NM_000267.3) | Missense Mutation (SNP) | VAF 76/250 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- OVCH1 | c.3305A>T p.K1102I | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDH7 | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- RIF1 | c.3283A>G p.T1095A | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SACS | c.5278C>G p.L1760V | Missense Mutation (SNP) | VAF 77/258 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SHOC1 | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- SLC22A12 | c.1598+1G>C p.X533_splice | Splice Site (SNP) | VAF 152/518 reads (29%) | called by muse, mutect2, varscan2
- SLC5A8 | c.1812G>C p.K604N | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SMC4 | c.611A>T p.K204M | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, varscan2
- SNRNP40 | c.83_85del p.A28del | In Frame Del (DEL) | VAF 35/130 reads (27%) | called by mutect2, pindel, varscan2
- SVIL | c.845A>G p.H282R | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- TEAD1 | c.1096_1098del p.I366del | In Frame Del (DEL) | VAF 86/341 reads (25%) | called by mutect2, pindel, varscan2
- TRIO | c.2164C>T p.Q722* | Nonsense Mutation (SNP) | VAF 66/219 reads (30%) | called by muse, mutect2, varscan2
- TTK | c.1694T>A p.L565H | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- UNC79 | c.7830G>C p.W2610C (on ENST00000393151 / NM_001346218.2; = p.W2433C on NM_020818.5) | Missense Mutation (SNP) | VAF 128/231 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VANGL1 | c.1411G>A p.V471M | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WTIP | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ZNF16 | c.1411A>C p.S471R | Missense Mutation (SNP) | VAF 269/590 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF232 | c.740A>G p.E247G | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZSCAN16 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 63/244 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM12 | c.594T>C p.S198= | Silent (SNP) | VAF 28/101 reads (28%) | called by muse, mutect2, varscan2
- AHNAK2 | c.10008G>A p.P3336= | Silent (SNP) | VAF 317/545 reads (58%) | catalogued as rs574127927; called by muse, mutect2, varscan2
- AMOTL1 | c.2673C>A p.A891= | Silent (SNP) | VAF 75/262 reads (29%) | called by muse, mutect2, varscan2
- BLCAP | c.264A>G p.*88= | Silent (SNP) | VAF 78/216 reads (36%) | catalogued as rs1219550472; called by muse, mutect2, varscan2
- CACNA1D | c.732G>A p.V244= | Silent (SNP) | VAF 86/293 reads (29%) | catalogued as rs372345315; called by muse, mutect2, varscan2
- CCDC148 | c.126T>C p.A42= | Silent (SNP) | VAF 20/76 reads (26%) | called by muse, mutect2, varscan2
- COL12A1 | c.4986G>A p.K1662= | Silent (SNP) | VAF 35/121 reads (29%) | called by muse, mutect2, varscan2
- DCAF12L2 | c.564C>T p.G188= | Silent (SNP) | VAF 313/435 reads (72%) | catalogued as rs1224019540, COSV63583763; called by muse, mutect2, varscan2
- DENND2C | c.309C>T p.D103= | Silent (SNP) | VAF 128/404 reads (32%) | catalogued as rs377134241; called by muse, mutect2, varscan2
- EFCAB6 | c.4479C>T p.N1493= | Silent (SNP) | VAF 42/132 reads (32%) | catalogued as rs143867838; called by muse, mutect2, varscan2
- ENDOG | c.318C>T p.G106= | Silent (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- FAM110B | c.252G>A p.P84= | Silent (SNP) | VAF 56/242 reads (23%) | catalogued as rs1292330760; called by muse, mutect2, varscan2
- HECTD4 | c.4545C>T p.H1515= | Silent (SNP) | VAF 42/133 reads (32%) | catalogued as rs762242239, COSV66389484; called by muse, mutect2, varscan2
- KCND3 | c.879C>T p.R293= | Silent (SNP) | VAF 110/343 reads (32%) | catalogued as rs147739517; ClinVar: likely benign; called by muse, mutect2, varscan2
- LOXL2 | c.282C>T p.H94= | Silent (SNP) | VAF 44/149 reads (30%) | catalogued as rs745627354; called by muse, mutect2, varscan2
- MED17 | c.24G>A p.R8= | Silent (SNP) | VAF 55/208 reads (26%) | catalogued as rs773807541; called by muse, mutect2, varscan2
- MRE11 | c.1065T>A p.S355= | Silent (SNP) | VAF 68/234 reads (29%) | called by muse, mutect2, varscan2
- MUC5B | c.7599A>G p.T2533= | Silent (SNP) | VAF 104/464 reads (22%) | catalogued as rs561572250; called by muse, varscan2
- NCR3LG1 | c.105T>A p.T35= | Silent (SNP) | VAF 77/260 reads (30%) | called by muse, mutect2, varscan2
- OR5B12 | c.318C>T p.I106= | Silent (SNP) | VAF 70/240 reads (29%) | called by muse, varscan2
- PGM1 | c.801C>G p.T267= | Silent (SNP) | VAF 74/267 reads (28%) | catalogued as COSV64301197; called by muse, mutect2, varscan2
- PKNOX2 | c.1140C>T p.I380= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as rs200196787; called by muse, mutect2, varscan2
- PRKAA2 | c.138C>T p.I46= | Silent (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- PRKCD | c.171G>A p.S57= | Silent (SNP) | VAF 105/350 reads (30%) | catalogued as rs782264326, COSV100387888; called by muse, mutect2, varscan2
- PRR36 | c.657G>A p.E219= | Silent (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- PSMA2 | c.270T>C p.A90= | Silent (SNP) | VAF 18/116 reads (16%) | called by muse, mutect2, varscan2
- RASIP1 | c.2661T>C p.P887= | Silent (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- RDH13 | c.519G>T p.S173= (on ENST00000415061 / NM_001145971.2; = p.S102= on NM_138412.4) | Silent (SNP) | VAF 102/340 reads (30%) | called by muse, mutect2, varscan2
- RELN | c.5838C>T p.I1946= | Silent (SNP) | VAF 76/376 reads (20%) | catalogued as rs759612378, COSV58994923, COSV59025189; called by muse, mutect2, varscan2
- RELN | c.876G>A p.A292= | Silent (SNP) | VAF 87/196 reads (44%) | catalogued as rs757968034, COSV59008270; called by muse, mutect2, varscan2
- RGPD3 | c.63G>A p.S21= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as rs749219712, COSV58737261; called by muse, mutect2, varscan2
- RYR1 | c.3144C>T p.Y1048= | Silent (SNP) | VAF 90/259 reads (35%) | catalogued as rs143242075; ClinVar: likely benign; called by muse, mutect2, varscan2
- SAGE1 | c.2565T>C p.S855= | Silent (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2, varscan2
- SCAI | c.1305G>A p.S435= (on ENST00000336505 / NM_001144877.3; = p.S458= on NM_173690.5) | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs750086633; called by muse, mutect2, varscan2
- SIX6 | c.345A>T p.V115= | Silent (SNP) | VAF 48/235 reads (20%) | called by muse, mutect2, varscan2
- SLCO6A1 | c.15C>T p.V5= | Silent (SNP) | VAF 73/153 reads (48%) | catalogued as rs1561510325, COSV65806577; called by muse, mutect2, varscan2
- ST6GAL2 | c.483G>T p.G161= | Silent (SNP) | VAF 39/368 reads (11%) | called by muse, mutect2, varscan2
- SYT17 | c.1353G>A p.V451= | Silent (SNP) | VAF 41/68 reads (60%) | catalogued as rs751861504; called by muse, mutect2, varscan2
- TBCC | c.127C>A p.R43= | Silent (SNP) | VAF 80/239 reads (33%) | called by muse, mutect2, varscan2
- TCIRG1 | c.243G>A p.P81= | Silent (SNP) | VAF 54/170 reads (32%) | catalogued as rs756073508; called by muse, mutect2, varscan2
- TMEM232 | c.1935C>G p.T645= | Silent (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.1029del | RNA (DEL) | VAF 18/34 reads (53%) | catalogued as rs541299432; called by mutect2, varscan2
- ATP11C | c.3298-715C>T | Intron (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- CERKL | c.1211+41del | Intron (DEL) | VAF 60/233 reads (26%) | called by mutect2, pindel, varscan2
- CHD6 | c.974+15A>C | Intron (SNP) | VAF 28/164 reads (17%) | called by muse, mutect2, varscan2
- EXOC2 | c.-34C>G | 5'UTR (SNP) | VAF 25/75 reads (33%) | called by muse, mutect2, varscan2
- GOLGA2 | c.526-11C>G | Intron (SNP) | VAF 37/110 reads (34%) | called by muse, mutect2, varscan2
- HERC2 | c.13273-313G>A | Intron (SNP) | VAF 71/252 reads (28%) | catalogued as rs551555052; called by muse, mutect2, varscan2
- ITGA9 | c.1839+45C>T | Intron (SNP) | VAF 125/439 reads (28%) | called by muse, mutect2, varscan2
- KAT6A | c.1483-1714T>A | Intron (SNP) | VAF 50/186 reads (27%) | catalogued as rs1332694245; called by muse, mutect2, varscan2
- KLHL7 | c.1380-9_1380-8insG | Intron (INS) | VAF 151/344 reads (44%) | called by mutect2, pindel, varscan2
- LINC01804 | n.450G>C | RNA (SNP) | VAF 28/99 reads (28%) | called by muse, mutect2, varscan2
- MAD2L2 | c.427+18C>A | Intron (SNP) | VAF 114/210 reads (54%) | called by muse, mutect2, varscan2
- MIR134 | n.71C>T | RNA (SNP) | VAF 31/111 reads (28%) | called by muse, mutect2, varscan2
- NDUFA5 | c.66+182A>T | Intron (SNP) | VAF 68/308 reads (22%) | called by muse, mutect2
- NDUFA5 | c.66+180T>G | Intron (SNP) | VAF 68/305 reads (22%) | called by muse, mutect2
- OR7A2P | n.904G>A | RNA (SNP) | VAF 6/13 reads (46%) | catalogued as rs529584892; called by muse, varscan2
- OR7A2P | n.220G>T | RNA (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- PRKN | c.*8G>A | 3'UTR (SNP) | VAF 75/261 reads (29%) | catalogued as rs368253350; called by muse, mutect2, varscan2
- RALGPS1 | c.1645-1829C>T | Intron (SNP) | VAF 33/113 reads (29%) | catalogued as rs770974658; called by muse, mutect2, varscan2
- RPL27A | c.68-124G>C | Intron (SNP) | VAF 28/98 reads (29%) | catalogued as rs538052428; called by muse, mutect2, varscan2
- SNORD114-31 | n.67G>C | RNA (SNP) | VAF 27/50 reads (54%) | called by muse, mutect2, varscan2
- STXBP5L | c.2248+6016G>C | Intron (SNP) | VAF 28/110 reads (25%) | catalogued as rs1031133745; called by muse, mutect2, varscan2
- TNPO2 | c.-13-358C>T | Intron (SNP) | VAF 12/38 reads (32%) | catalogued as COSV63509647; called by muse, mutect2, varscan2
- TRPM4 | c.3329-10G>A | Intron (SNP) | VAF 73/249 reads (29%) | catalogued as rs764962434, COSV53261523; called by muse, mutect2, varscan2
- TTC3P1 | n.4687A>G | RNA (SNP) | VAF 48/149 reads (32%) | called by muse, mutect2, varscan2
- Unknown | chr8:74752522 G>T | IGR (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- WT1 | chr11:32439694 C>T | 5'Flank (SNP) | VAF 103/319 reads (32%) | catalogued as rs1201597748; called by muse, mutect2, varscan2
